Somatic mutation profile of tumor specimen 1105259 (aliquot 7316UP-35-1105259) from CPTAC case C219555, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Temporal lobe; Tumor grade: G4.
Specimen 1105259: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 45b4f971-7095-4b38-affa-78801219be85.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105285 (Blood Derived Normal), aliquot 7316UP-334-1105285; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ac2c29f6-24ba-4d68-8835-2332343bf9eb

The open-access MAF lists 98 somatic variants for this specimen: 67 protein-altering or splice-affecting, 18 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 18, Intron 6, Splice Site 3, Nonsense Mutation 3, 5'UTR 3, 3'Flank 1, RNA 1, Splice Region 1, In Frame Del 1, Frame Shift Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KDR | c.3094C>T p.R1032* | Nonsense Mutation (SNP) | VAF 81/293 reads (28%) | hotspot (GDC flag); catalogued as rs767542615, COSV55758800; called by muse, mutect2, varscan2
- ABCC5 | c.3842G>T p.S1281I | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.494); catalogued as rs377607475; called by muse, mutect2, varscan2
- ALOX5 | c.437T>C p.M146T | Missense Mutation (SNP) | VAF 88/118 reads (75%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV65551322; called by muse, mutect2, varscan2
- CDH2 | c.1133A>G p.N378S | Missense Mutation (SNP) | VAF 37/192 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs199977445; called by muse, mutect2, varscan2
- COL6A3 | c.5179C>T p.R1727W | Missense Mutation (SNP) | VAF 162/441 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs143074017; ClinVar: uncertain significance / benign; called by muse, mutect2, varscan2
- COX6B2 | c.143G>A p.R48H | Missense Mutation (SNP) | VAF 38/766 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.927); catalogued as rs540732232; called by muse, mutect2
- EOMES | c.184G>C p.E62Q | Missense Mutation (SNP) | VAF 26/739 reads (4%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as COSV55413140; called by muse, mutect2
- FGD5 | c.3781C>T p.R1261C | Missense Mutation (SNP) | VAF 89/357 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs867308143; called by muse, mutect2, varscan2
- FLG | c.6350C>T p.S2117F | Missense Mutation (SNP) | VAF 60/496 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as rs1198846753; called by muse, mutect2, varscan2
- FLT4 | c.1426C>T p.R476W | Missense Mutation (SNP) | VAF 133/664 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs756924526, COSV56100948; called by muse, mutect2, varscan2
- GLUD2 | c.232G>A p.A78T | Missense Mutation (SNP) | VAF 166/403 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as rs200880803, COSV60151559, COSV60152177; called by muse, mutect2, varscan2
- JPH4 | c.1463C>T p.P488L | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs781359993, COSV58115528; called by muse, mutect2, varscan2
- KCNA4 | c.1621G>A p.G541R | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761722050; called by muse, mutect2, varscan2
- KCNG2 | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 42/179 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as rs769581960, COSV60267267; called by muse, mutect2, varscan2
- KIF2C | c.2168G>A p.R723Q | Missense Mutation (SNP) | VAF 46/174 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as rs201647887; called by muse, mutect2, varscan2
- MAP3K21 | c.2519C>T p.P840L | Missense Mutation (SNP) | VAF 95/193 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.04); catalogued as COSV64042498; called by muse, mutect2, varscan2
- MMP17 | c.1076G>A p.R359Q | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.389); catalogued as rs778678410, COSV100861958; called by muse, mutect2, varscan2
- MYO15A | c.6248C>A p.A2083E | Missense Mutation (SNP) | VAF 20/564 reads (4%) | SIFT tolerated (0.81); PolyPhen benign (0.037); catalogued as COSV52758572; called by muse, mutect2
- PCLO | c.4503_4505del p.D1502del | In Frame Del (DEL) | VAF 23/176 reads (13%) | catalogued as rs1167912382; called by pindel, varscan2
- PDILT | c.979C>T p.R327W | Missense Mutation (SNP) | VAF 47/267 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs199754421, COSV56700754; called by muse, mutect2, varscan2
- POLN | c.541G>A p.A181T | Missense Mutation (SNP) | VAF 45/189 reads (24%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as rs777556943; called by muse, mutect2, varscan2
- PROM2 | c.1427+1G>A p.X476_splice | Splice Site (SNP) | VAF 11/44 reads (25%) | catalogued as rs200030602, COSV58298084; called by muse, mutect2, varscan2
- RASGEF1C | c.1112T>A p.I371N | Missense Mutation (SNP) | VAF 53/249 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100746152; called by muse, mutect2, varscan2
- RFPL1 | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 154/381 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.033); catalogued as rs150980053; called by muse, mutect2, varscan2
- RIPK4 | c.2393C>T p.T798M (on ENST00000352483; = p.T750M on NM_020639.3) | Missense Mutation (SNP) | VAF 51/326 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs775167583; called by muse, mutect2, varscan2
- ROBO4 | c.1324G>C p.A442P | Missense Mutation (SNP) | VAF 27/47 reads (57%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs774752196; called by muse, mutect2, varscan2
- SLFN13 | c.1016G>A p.R339H | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT tolerated (0.58); PolyPhen benign (0.285); catalogued as rs148604980; called by muse, mutect2, varscan2
- ST8SIA2 | c.810C>A p.Y270* | Nonsense Mutation (SNP) | VAF 111/385 reads (29%) | catalogued as rs1375310199, COSV51571832; called by muse, mutect2, varscan2
- TECTA | c.5224C>T p.R1742C | Missense Mutation (SNP) | VAF 10/229 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1247677993, COSV50716036; called by muse, mutect2
- TMEM201 | c.1343G>A p.R448H | Missense Mutation (SNP) | VAF 24/382 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1052004972; called by muse, mutect2
- USP43 | c.1007G>A p.R336Q | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs927663097; called by muse, mutect2, varscan2
- WDR72 | c.2866C>T p.R956* | Nonsense Mutation (SNP) | VAF 17/172 reads (10%) | catalogued as rs751269504, COSV64743965; called by muse, mutect2
- ZNF202 | c.356C>T p.T119M | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1169707380; called by muse, mutect2, varscan2
- ZNF697 | c.407C>T p.P136L | Missense Mutation (SNP) | VAF 44/147 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs780817187, COSV70284299; called by muse, mutect2, varscan2
- ANO3 | c.1189G>T p.A397S | Missense Mutation (SNP) | VAF 61/161 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- ARHGAP39 | c.1414G>T p.A472S | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- BLK | c.808A>G p.T270A | Missense Mutation (SNP) | VAF 22/489 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.277); called by muse, mutect2
- BTC | c.115C>A p.P39T | Missense Mutation (SNP) | VAF 33/144 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- CACNB4 | c.522-3T>A | Splice Region (SNP) | VAF 16/107 reads (15%) | called by muse, mutect2, varscan2
- CHD1L | c.2657A>G p.Q886R | Missense Mutation (SNP) | VAF 29/151 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- DSP | c.8119A>T p.M2707L | Missense Mutation (SNP) | VAF 63/135 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EGFR | c.805C>G p.L269V | Missense Mutation (SNP) | VAF 590/5190 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, varscan2
- GABRA6 | c.570A>T p.K190N | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT tolerated (0.23); PolyPhen probably damaging (1); called by muse, mutect2
- HERC2P3 | n.1061-2A>T | Splice Site (SNP) | VAF 96/869 reads (11%) | called by muse, mutect2, varscan2
- IL3RA | c.995A>T p.Q332L | Missense Mutation (SNP) | VAF 33/195 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- KHSRP | c.1702G>A p.A568T | Missense Mutation (SNP) | VAF 58/327 reads (18%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- LRRIQ3 | c.1520A>G p.E507G | Missense Mutation (SNP) | VAF 37/192 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- MAGEB3 | c.215C>A p.T72N | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- MC2R | c.365C>T p.S122F | Missense Mutation (SNP) | VAF 212/534 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.548); called by muse, mutect2
- MUC16 | c.32816C>A p.T10939N | Missense Mutation (SNP) | VAF 33/225 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR2V1 | c.239C>A p.P80Q | Missense Mutation (SNP) | VAF 52/228 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR51E1 | c.692T>C p.L231S | Missense Mutation (SNP) | VAF 46/132 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- OXT | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 85/455 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PATL1 | c.1589A>G p.Y530C | Missense Mutation (SNP) | VAF 42/75 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- PCSK1N | c.722G>A p.R241H | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.375); called by muse, mutect2, varscan2
- PZP | c.1723C>G p.P575A | Missense Mutation (SNP) | VAF 38/249 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCN1A | c.1084T>A p.Y362N | Missense Mutation (SNP) | VAF 23/277 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- SCNN1G | c.122G>C p.C41S | Missense Mutation (SNP) | VAF 19/612 reads (3%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.903); called by muse, mutect2
- SLC13A1 | c.1032-1G>T p.X344_splice | Splice Site (SNP) | VAF 42/348 reads (12%) | called by muse, mutect2, varscan2
- SPHK2 | c.1670C>T p.P557L | Missense Mutation (SNP) | VAF 89/474 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- STXBP2 | c.43_44del p.L15Efs*38 | Frame Shift Del (DEL) | VAF 24/213 reads (11%) | called by mutect2, pindel, varscan2
- TMCC1 | c.1910A>G p.H637R (on ENST00000393238 / NM_001349268.2; = p.H313R on NM_015008.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 67/126 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.481); called by mutect2, varscan2
- TMEM30A | c.350A>G p.N117S | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- WDR41 | c.477C>A p.N159K | Missense Mutation (SNP) | VAF 26/175 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.457); called by muse, mutect2, varscan2
- ZNF449 | c.1523T>C p.M508T | Missense Mutation (SNP) | VAF 28/36 reads (78%) | SIFT tolerated (0.53); PolyPhen benign (0.242); called by muse, varscan2
- ZNF800 | c.1868G>A p.C623Y | Missense Mutation (SNP) | VAF 59/177 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF804B | c.1892T>C p.I631T | Missense Mutation (SNP) | VAF 11/144 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2
- CNTNAP3B | c.2070G>C p.P690= | Silent (SNP) | VAF 63/496 reads (13%) | called by muse, mutect2, varscan2
- CYP26B1 | c.855G>A p.E285= | Silent (SNP) | VAF 97/598 reads (16%) | catalogued as rs781438588; called by muse, mutect2, varscan2
- FOSL2 | c.705G>A p.S235= | Silent (SNP) | VAF 48/119 reads (40%) | catalogued as rs199702734; called by muse, mutect2, varscan2
- GALNT17 | c.714C>T p.T238= | Silent (SNP) | VAF 16/122 reads (13%) | catalogued as rs758291046, COSV61146047; called by muse, mutect2, varscan2
- GIMAP6 | c.298C>T p.L100= | Silent (SNP) | VAF 16/235 reads (7%) | called by muse, mutect2
- GPAT3 | c.285C>T p.D95= | Silent (SNP) | VAF 90/210 reads (43%) | catalogued as rs770258933, COSV52358359; called by muse, mutect2, varscan2
- GPD2 | c.12A>G p.Q4= | Silent (SNP) | VAF 70/199 reads (35%) | called by muse, mutect2, varscan2
- IGLV3-32 | c.48C>T p.S16= | Silent (SNP) | VAF 23/112 reads (21%) | catalogued as rs767509054; called by muse, mutect2, varscan2
- IL17A | c.303C>T p.N101= | Silent (SNP) | VAF 57/318 reads (18%) | catalogued as rs767532310; called by muse, mutect2, varscan2
- KCNH7 | c.627C>T p.S209= | Silent (SNP) | VAF 39/277 reads (14%) | catalogued as COSV59783341; called by muse, mutect2, varscan2
- LILRB4 | c.1239C>T p.Y413= (on ENST00000391733 / NM_001278428.3; = p.Y412= on NM_001278426.3) | Silent (SNP) | VAF 42/287 reads (15%) | catalogued as rs191773308; called by muse, varscan2
- LMBR1 | c.174G>A p.R58= | Silent (SNP) | VAF 19/134 reads (14%) | called by muse, mutect2, varscan2
- MC2R | c.324C>G p.S108= | Silent (SNP) | VAF 209/543 reads (38%) | called by muse, mutect2, varscan2
- NKX2-3 | c.852G>A p.A284= | Silent (SNP) | VAF 42/131 reads (32%) | catalogued as rs1237636234; called by muse, varscan2
- OSBPL8 | c.732C>A p.I244= | Silent (SNP) | VAF 12/224 reads (5%) | called by muse, mutect2
- PHOX2A | c.450C>T p.R150= | Silent (SNP) | VAF 14/414 reads (3%) | called by muse, mutect2
- PTH1R | c.90C>T p.D30= | Silent (SNP) | VAF 201/518 reads (39%) | catalogued as rs781370785; called by muse, mutect2, varscan2
- SETBP1 | c.147G>A p.P49= | Silent (SNP) | VAF 43/193 reads (22%) | catalogued as rs775091518, COSV56330089, COSV56336218; called by muse, mutect2, varscan2
- AC244197.3 | c.*21C>G | 3'UTR (SNP) | VAF 166/180 reads (92%) | catalogued as COSV100558192; called by muse, mutect2, varscan2
- AK2 | c.94-2746G>A | Intron (SNP) | VAF 226/555 reads (41%) | called by muse, mutect2, varscan2
- CHMP5 | c.-13G>C | 5'UTR (SNP) | VAF 94/126 reads (75%) | called by muse, mutect2, varscan2
- CYB5RL | chr1:54171196 C>T | 3'Flank (SNP) | VAF 150/434 reads (35%) | catalogued as rs564385397, COSV55276747; called by muse, mutect2, varscan2
- EPPIN-WFDC6 | c.522+416C>A | Intron (SNP) | VAF 42/251 reads (17%) | called by muse, mutect2, varscan2
- FLYWCH1 | c.1514-277G>A | Intron (SNP) | VAF 28/52 reads (54%) | catalogued as rs1038542024; called by muse, mutect2, varscan2
- GGTLC2 | chr22:22642894 G>A | 5'Flank (SNP) | VAF 332/720 reads (46%) | called by muse, mutect2, varscan2
- GPSM1 | c.1207+59C>T | Intron (SNP) | VAF 66/267 reads (25%) | called by muse, mutect2, varscan2
- IGLV2-14 | c.-2C>A | 5'UTR (SNP) | VAF 45/128 reads (35%) | called by muse, mutect2
- LINC01036 | n.285C>A | RNA (SNP) | VAF 14/445 reads (3%) | called by muse, mutect2
- TGM6 | c.-66G>A | 5'UTR (SNP) | VAF 113/277 reads (41%) | catalogued as rs764830062; called by muse, mutect2, varscan2
- TTN | c.30475+13G>C | Intron (SNP) | VAF 35/90 reads (39%) | called by muse, mutect2, varscan2
- UTY | c.152+25G>A | Intron (SNP) | VAF 192/216 reads (89%) | catalogued as rs750427743; called by muse, mutect2, varscan2
